Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16F, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16F-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Adenocarcinoma, Endometrioid, NOS

8380/3 12/9/10

Surgical Pathology Site Code: Endometrium C54.1

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 B1 B2 C1 C2 C3 C4 C5 D1 E1
E2 E3 E4
F1 F2 G1 G2 G3 G4
Uterus (82.21 grams), right ovary (2.9 x 2.5 x 0.7 cm)
with 7.5 cm
segment of right fallopian tube, and separately submitted
left ovary
(2.5 x 2.0 x 1.3 cm) with 4.0 cm segment of left fallopian
tube,
right and left pelvic lymph nodes (laparoscopically),
right and left
para-aortic lymph nodes above and below the inferior
mesenteric
artery (laparoscopically).

DIAGNOSIS:

Uterus, hysterectomy: Endometrial adenocarcinoma,
endometrioid
type, FIGO grade II (of III) endometrioid type, forming a
polypoid
mass (7.5 x 2.5 x 1.3 cm). The tumor, which demonstrates
focal
squamous differentiation, invades the myometrium to a
maximal depth
of 0.5 cm (2.0 cm total myometrial thickness) and extends
to involve
the lower uterine segment. The cervix is uninvolved.

Ovary and fallopian tube, right salpingo-oophorectomy: No
diagnostic abnormalities.

Ovary and fallopian tube, left salpingo-oophorectomy: No
diagnostic
abnormalities.

Lymph nodes, right pelvic, lymphadenectomy: Multiple (5)
right
pelvic lymph nodes are negative for tumor.

Lymph nodes, left pelvic, lymphadenectomy: Multiple (10)
left

[page 2 of 2]
pelvic lymph nodes are negative for tumor.

Lymph nodes, right and left para-aortic, lymphadenectomy:
Multiple
(5 above the inferior mesenteric artery and 1 below the
inferior
mesenteric artery) para-aortic lymph nodes are negative
for tumor.

This final pathology report is based on the
gross/macroscopic
examination and frozen section histologic evaluation of
the
specimen(s).

Source: NCI Genomic Data Commons file f316f5b4-654a-49d8-9a3d-640ee417187d (TCGA-D1-A16F.E89C4CBF-45D5-405D-A673-F67186C206B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).